Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A1AK, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A1AK-01A (Primary Tumor).

ICD-0-3

Carcinoma, lobular, infiltrating 8520/3

Site code: breast, NOS C50.9

12/24/10 lw

Final diagnosis

Breast, right, simple mastectomy: Invasive mammary carcinoma, Nottingham grade II (of III), with predominantly lobular features is identified forming multiple (4) masses (ranging in size from 0.7 cm to 1.6 cm in greatest dimension) (AJCC pTc) situated in multiple quadrants (lower inner quadrant, inferior central, upper outer quadrant, and 12 o' clock position). There is a minimal (5%) component of ductal carcinoma in situ, intermediate nuclear grade. No angiolymphatic invasion identified. Tumor closely approaches (0.1 cm) the original inferior margin. Skin, nipple, and final surgical margins (after re-excision) are negative for tumor.

Lymph nodes, right axillary sentinel, excision: Multiple (5) right axillary sentinel lymph nodes are negative for tumor (AJCCpN0(sn)(i-)). Blue dye is identified in all five right axillary sentinel lymph nodes. Immunohistochemical cytokeratin stain was performed on the paraffin embedded sentinel lymph node tissue and confirms the H&E impression.

HER2/neu protein overexpression is negative, score of 1+, according to the interpretation guidelines in the FDA-approved HercepTest.

Source: NCI Genomic Data Commons file 57e226f8-23ab-4142-bf58-8de68ca4985e (TCGA-AR-A1AK.F4DBFC71-9CD0-41C3-9F20-77FA0605D4A8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).